Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A2EA, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A2EA-01A (Primary Tumor).

Subtotal resection of thyroid gland	Complexes of cells forming papillary structures with marked cellular and nuclear polymorphism. Nucleus large and medium-sized, irregular contour of the membrane	Papillary thyroid cancer with diffuse growth.	Histologic type: Papillary thyroid carcinoma	Right
-------------------------------------	--	---	--	-------

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, Nos C73.9

for
6/1/11

Source: NCI Genomic Data Commons file c03aa09f-4660-45b7-a361-cc60d27f64a1 (TCGA-E8-A2EA.ABFB455E-221D-420A-8B0B-0803BEBF8EBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).